Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6369, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6369-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. PROSTATE
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES

TCGA-G9-6369

SPECIMEN(S):

- A. PROSTATE
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the patient's identification and "prostate" is a 36-g resected prostate gland measuring 3.6 cm from left lateral to right lateral, 2.8 cm from anterior to posterior, and 2.7 cm from apex to base. The capsule is smooth, red, and intact. Ink code: anterior-orange, apex-red, base-blue, right lateral-green, left lateral-yellow, posterior-black. After removal of the apex and base, the prostate weighs 22 g. The parenchyma has a nodular tan appearance. Alternating sections are submitted for tissue procurement (9 g). The right seminal vesicle is torn and 4.3 x 1.6 x 0.6 cm, the left is 3.7 x 1.4 x 0.6 cm. They consist of cystic tan tissue. The vas deferens are detached from the prostate and measure 1.6 x 0.6 cm and 2.2 x 0.8 cm; they are made up of tubular tan tissue. Submitted entirely:

- A1: right apex, perpendicular sections
- A2-A3: left apex, perpendicular sections
- A4: level 1, right anterior
- A5: level 1, right posterior
- A6: level 1, left anterior
- A7: level 1, left posterior
- A8: level 2, anterior and right lateral capsule
- A9: level 2, posterior and left lateral capsule
- A10: level 3, right anterior
- A11: level 3, right posterior
- A12: level 3, left anterior
- A13: level 3, left posterior
- A14: level 4, anterior and right lateral capsule
- A15: level 4, posterior and left lateral capsule
- A16: right mid base, perpendicular sections
- A17: left mid base, perpendicular sections
- A18-A20: right lateral base, perpendicular sections
- A21-A22: left lateral base, perpendicular sections
- A23: right posterior base
- A24: left posterior base
- A25: right seminal vesicle
- A26: left seminal vesicle
- A27: vas deferens

B. RIGHT PELVIC LYMPH NODES

Received fresh labeled with the patient's identification and "right pelvic lymph nodes" are pieces of yellow-tan soft tissue in aggregate, 5.4 x 3.7 x 1.5 cm; multiple lymph nodes are identified ranging from 0.1 to 1.7 cm. Lymph nodes are submitted entirely as follows:

- B1: 6 lymph nodes
- B2: 2 lymph nodes
- B3: 5 lymph nodes
- B4: 1 lymph node
- B5: 1 lymph node

C. LEFT PELVIC LYMPH NODES

Received fresh labeled with the patient's identification and "left pelvic lymph nodes" are pieces of yellow-tan soft tissue in aggregate, 5.7 x 4.6 x 1-cm containing multiple lymph nodes ranging from 0.3 to 2.4 cm. Lymph nodes are submitted entirely as follows:

- C1: 6 lymph nodes
- C2-C5: 1 lymph node in each cassette

DIAGNOSIS:

A. PROSTATE, RADICAL PROSTATECTOMY:

- PROSTATE ADENOCARCINOMA, GLEASON SCORE 4 + 3 (7/10) INVOLVING

[page 2 of 2]
APPROXIMATELY 4% OF EXAMINED TISSUE.

- RESECTION MARGINS AND SEMINAL VESICLES ARE NOT INVOLVED

B. LYMPH NODES, RIGHT PELVIC, DISSECTION:

- TWELVE BENIGN LYMPH NODES (0/12).

C. LYMPH NODES, LEFT PELVIC, DISSECTION:

- NINE BENIGN LYMPH NODES (0/9).

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

Location: Left

Right

Posterior lateral

Basal

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 4%

Gleason Grade/Sum:: Grade 4 + 3 , Sum 7

High Grade PIN Present: No

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: No

Bladder Neck Involved: No

Margins Involvement: No

Frozen Performed: No

Lymph Nodes: Negative Right 0 / 12 Left 0 / 9

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 2c N 0 M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Source: NCI Genomic Data Commons file 61075d1e-03d8-417f-80e4-5c73d6a4309b (TCGA-G9-6369.8DA381E8-6BAB-4B75-9AE3-D7B76F90F044.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).